Surgical pathology report (de-identified scan), TCGA case TCGA-19-0960, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-0960-01A (Primary Tumor).

TCGA-19-0960

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

A, B. LEFT PARIETAL LOBE OF BRAIN, TUMOR, BIOPSY AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: The bulk of the tumor is represented in specimen A. Specimen B. demonstrates relatively normal-appearing neural parenchyma containing infiltrating glioma cells.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A. Microscopic: Glioblastoma

Clinical History:

Brain tumor

Specimens Submitted As:

A: LEFT PARIETAL TUMOR

B: PARIETAL TUMOR

Gross Description:

A: Received fresh for intraoperative consultation, labeled with the patient's name, hospital number and "left parietal tumor," is an irregular segment of white-pink soft tissue, 0.7 x 0.6 x 0.2 cm. A portion of the specimen is used for a touch imprint. The rest of the specimen is submitted for permanents.

B: Received fresh, post-fixed in formalin, labeled with the patient's name, number, and "L. parietal tumor", are three light tan to pink irregular soft tissue fragments measuring 0.5 x 0.2 x 0.1 cm, 1.1 x 0.45 x 0.25 cm, and 2.0 x 1.3 x 0.9 cm. The largest fragment is serially sectioned. On section, the tissue is light tan to pink. Submitted entirely in 3 cassettes.

Summary of Cassettes:

Specimen	Label	Site
B	1,2	large fragment
	3	remaining tissue

Source: NCI Genomic Data Commons file 27740a57-2eff-404b-91c5-8fe06d30329d (TCGA-19-0960.3E154285-F66B-4C5C-912B-02AE5762397D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).